Gene-level copy-number profile of tumor specimen TCGA-DX-A3LW-01A from TCGA case TCGA-DX-A3LW, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 43.7 years (15,969 days).
Specimen TCGA-DX-A3LW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.f9c61f8b-163b-4059-92be-f2be0c1a8913.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3LW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/17ee9d7f-c501-4438-b390-58422f4795e2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 8; copy number 2: 6,553; copy number 3: 2,990; copy number 4: 44,279; copy number 5: 4,258; copy number 6: 1,053; copy number 7: 5; copy number 8: 82; copy number 9: 74; copy number 11: 124; copy number 13: 6; copy number 14: 6; copy number 15: 101; copy number 16: 79; copy number 17: 2; copy number 18: 1; copy number 19: 5; copy number 21: 11; copy number 22: 10; copy number 24: 11; copy number 25: 7; copy number 26: 38; copy number 27: 15; copy number 33: 11; copy number 35: 13; copy number 36: 7; copy number 37: 37; copy number 38: 21; copy number 48: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3LW-01A-21D-A21P-01): tumor purity 0.9, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 581 genes in 39 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:182,573,634–182,684,576, 5 genes, copy number 9 (within-gene range 4–9): RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8.
- chr1:188,242,139–194,719,236, 61 genes, copy number 9 (broad region; genes not listed).
- chr4:13,333,414–14,242,813, 16 genes, copy number 9–21: HSP90AB2P, RAB28, AC006445.3, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1, LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1.
- chr4:17,800,655–18,021,876, 4 genes, copy number 24: DCAF16, NCAPG, LCORL, KRT18P63.
- chr4:25,529,177–26,104,258, 15 genes, copy number 37 (within-gene range 4–37): AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11, AC092436.2, MTND4P9, MTND4LP22, MTND3P5, MTCO3P44, SEL1L3, AC092436.3, SMIM20, AC133961.1, LINC02357.
- chr4:27,964,517–27,985,063, 1 gene, copy number 11 (within-gene range 4–11): AC007106.1.
- chr4:28,996,498–31,351,725, 18 genes, copy number 19–36: LINC02364, AC068944.2, AC068944.1, AC109349.1, LINC02472, AC092593.2, AC092593.1, U6, EEF1A1P21, AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1.
- chr4:31,997,376–32,353,220, 3 genes, copy number 26: LINC02506, AC097654.1, LINC02353.
- chr4:33,010,948–33,238,670, 3 genes, copy number 15: MAPRE1P2, AC093606.1, AC093878.1.
- chr4:34,966,241–35,496,003, 3 genes, copy number 9–25: AC020589.1, SEC63P2, RNU6-573P.
- chr4:36,244,116–36,641,939, 6 genes, copy number 13: AC104078.1, DTHD1, AC104078.2, MIR1255B1, LINC02505, AC125336.1.
- chr4:37,866,561–39,666,879, 43 genes, copy number 11 (within-gene range 6–11): AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3, RNA5SP158, TLR10, TLR1, TLR6, FAM114A1, MIR574, TMEM156, KLHL5, AC079921.1, AC079921.2, WDR19, RFC1, RNU6-32P, RNU6-887P, KLB, MIR5591, Y_RNA, RPL9, LIAS, AC021148.1, UGDH, UGDH-AS1, AC021148.2, SMIM14, AC108471.3, RNU7-11P, AC108471.2.
- chr4:40,042,917–40,377,513, 12 genes, copy number 27: AC098591.2, N4BP2, RNU6-1112P, AC098591.1, AC095057.1, AC095057.3, AC095057.4, RHOH, AC095057.2, LINC02265, CHRNA9, RNU7-74P.
- chr12:38,078,529–38,087,392, 2 genes, copy number 16: AK6P2, CLUHP8.
- chr12:39,447,404–39,467,345, 2 genes, copy number 17: AC121334.4, AC121334.1.
- chr12:42,157,104–42,238,349, 1 gene, copy number 15 (within-gene range 4–15): YAF2.
- chr12:43,353,866–43,661,101, 5 genes, copy number 14 (within-gene range 4–14): ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17.
- chr12:44,498,616–44,503,596, 2 genes, copy number 27: AC025253.1, AC025253.2.
- chr12:47,463,087–48,011,227, 24 genes, copy number 11 (within-gene range 6–11): ADI1P3, AC003686.1, AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5.
- chr12:48,507,354–48,562,956, 3 genes, copy number 11: AC089987.1, OR8S1, OR5BS1P.
- chr12:51,809,705–52,618,559, 51 genes, copy number 15–38: AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN, NR4A1, NR4A1AS, ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1, LINC00592, KRT80, LINC02874, METTL7AP1, KRT7, KRT7-AS, KRT86, KRT87P, AC021066.2, AC021066.1, AC021066.3, KRT81, AC121757.2, AC121757.1, KRT83, KRT89P, KRT85, KRT84, AC078865.1, KRT82, AC055736.1, KRT90P, KRT75, KRT6B, KRT6C, KRT6A, KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73.
- chr12:52,674,736–52,680,407, 1 gene, copy number 21: KRT1.
- chr12:53,739,611–56,038,435, 131 genes, copy number 11–37 (within-gene range 4–37) (broad region; genes not listed).
- chr12:56,202,179–57,226,449, 57 genes, copy number 16: RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2, HSPD1P4, RBMS2, RNU6-343P, BAZ2A, ATP5F1B, SNORD59A, PTGES3, RN7SL809P, NACA, AC117378.1, PRIM1, HSD17B6, AC121758.2, AC121758.4, AC121758.3, AC121758.1, SDR9C7, AC026120.2, RDH16, AC026120.1, AC026120.3, GPR182, ZBTB39, TAC3, MYO1A, NEMP1, NAB2, STAT6, LRP1, LRP1-AS, MIR1228, NXPH4.
- chr12:57,674,665–57,968,399, 26 genes, copy number 26: RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1.
- chr12:58,565,959–58,781,747, 1 gene, copy number 14 (within-gene range 3–32): LINC02388.
- chr12:63,142,759–63,272,336, 3 genes, copy number 38: AVPR1A, AC135584.1, HNRNPA1P69.
- chr12:64,032,412–64,147,857, 5 genes, copy number 25: AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1.
- chr12:64,404,392–64,977,509, 20 genes, copy number 16 (within-gene range 5–16): XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39.
- chr12:65,758,020–65,826,997, 1 gene, copy number 48: RPSAP52.
- chr12:65,830,750–65,831,050, 1 gene, copy number 48: AC107308.1.
- chr12:67,443,105–68,451,663, 18 genes, copy number 11–26 (within-gene range 4–26): LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1.
- chr12:68,805,011–68,971,570, 9 genes, copy number 35: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,825,227–70,920,738, 14 genes, copy number 11–33 (within-gene range 4–33): MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr12:71,007,773–71,441,898, 4 genes, copy number 36 (within-gene range 4–38): AC123905.1, AC025575.1, AC025575.2, TSPAN8.
- chr12:72,610,678–73,208,317, 5 genes, copy number 11: CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1.
- chr12:75,649,195–75,691,937, 1 gene, copy number 27 (within-gene range 4–27): AC078820.2.
- chr12:76,025,447–76,033,932, 3 genes, copy number 26: PHLDA1, AC011611.3, AC011611.4.
- chr12:78,052,181–78,091,737, 1 gene, copy number 24 (within-gene range 4–24): AC073571.1.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
